Somatic mutation profile of tumor specimen TCGA-NC-A5HF-01A (aliquot TCGA-NC-A5HF-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HF, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 74.0 years (27,038 days).
Specimen TCGA-NC-A5HF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bf92c44-dac0-4f95-9f51-2f51bd445709.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HF-10A (Blood Derived Normal), aliquot TCGA-NC-A5HF-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffeecf78-1163-4518-a795-f6adda4b7801

The open-access MAF lists 287 somatic variants for this specimen: 214 protein-altering or splice-affecting, 64 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 64, Nonsense Mutation 11, Frame Shift Del 9, Frame Shift Ins 5, Splice Site 4, Intron 4, Splice Region 2, Translation Start Site 1, RNA 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 32/78 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62572203, COSV62573812; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 39/57 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.1121T>A p.L374Q (on ENST00000373394 / NM_001271696.3; = p.L375Q on NM_004299.6) | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99504742; called by muse, mutect2, varscan2
- ACTR3 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99603938; called by muse, mutect2, varscan2
- ACTRT3 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV57755117; called by muse, mutect2, varscan2
- ADAM17 | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV100176488; called by muse, mutect2, varscan2
- ADAMTS16 | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57011725, COSV99942638; called by muse, mutect2, varscan2
- ADAMTS20 | c.3521C>A p.A1174D | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.991); catalogued as COSV101166383; called by muse, varscan2
- ADCY6 | c.2888G>T p.R963L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100326850; called by muse, mutect2, varscan2
- AKIRIN2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100005300; called by muse, mutect2, varscan2
- ALDH3B1 | c.1055T>A p.I352N | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV99142040; called by muse, mutect2, varscan2
- APOB | c.11507C>T p.A3836V | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as rs1315039387, COSV99267481; called by muse, mutect2, varscan2
- BIRC2 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99926879; called by muse, mutect2, varscan2
- BUB1 | c.1277G>C p.G426A | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100241566; called by muse, mutect2, varscan2
- C10orf71 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100110592; called by muse, varscan2
- C1orf94 | c.1072C>A p.P358T (on ENST00000488417 / NM_001134734.2; = p.P168T on NM_032884.5) | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.114); catalogued as COSV100975191, COSV64914504; called by muse, mutect2, varscan2
- C2orf16 | c.578T>A p.L193* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV101284412; called by muse, mutect2, varscan2
- CACNA1S | c.5374C>G p.L1792V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as rs1267035675, COSV100755312; called by muse, mutect2
- CACNA1S | c.4819C>G p.Q1607E | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100755314; called by muse, mutect2, varscan2
- CALB2 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100226396; called by muse, mutect2, varscan2
- CALCRL | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101131033, COSV66473886; called by muse, mutect2, varscan2
- CAPZA3 | c.754C>G p.L252V | Missense Mutation (SNP) | VAF 128/161 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV99856839; called by muse, mutect2, varscan2
- CASP1 | c.488G>T p.R163L (on ENST00000436863 / NM_033292.4; = p.R142L on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100782836; called by muse, mutect2, varscan2
- CBLN1 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99535790; called by muse, mutect2, varscan2
- CCNA2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); catalogued as COSV52655025, COSV99144834; called by muse, mutect2, varscan2
- CDCA7 | c.683G>A p.R228H (on ENST00000347703 / NM_145810.3; = p.R307H on NM_031942.5) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs749651449, COSV100143728; called by muse, mutect2, varscan2
- CEP170 | c.1232A>G p.Q411R | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100316286; called by muse, mutect2
- CHRDL1 | c.1247G>T p.G416V (on ENST00000372045; = p.G422V on NM_145234.4) | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV54328113, COSV99488613; called by muse, mutect2, varscan2
- CHRNB3 | c.817G>T p.V273F | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99251425; called by muse, mutect2, varscan2
- CNTNAP5 | c.866C>A p.T289K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV101444075; called by muse, mutect2, varscan2
- COL11A1 | c.4040C>A p.P1347H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100617898; called by muse, mutect2
- COL11A1 | c.4039C>A p.P1347T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100617899, COSV62184098; called by muse, mutect2
- COL12A1 | c.7376G>T p.G2459V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100486389; called by muse, mutect2, varscan2
- COL19A1 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552171890, COSV100507272; called by muse, mutect2, varscan2
- COL6A3 | c.5993G>T p.R1998L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99800809; called by muse, mutect2, varscan2
- CPNE3 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV52209194, COSV99548015; called by muse, mutect2, varscan2
- CSE1L | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99522203; called by muse, mutect2, varscan2
- CSMD1 | c.5227A>T p.S1743C (on ENST00000520002; = p.S1742C on NM_033225.6) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100152948; called by muse, mutect2, varscan2
- CSMD2 | c.6079G>T p.G2027C | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99594449; called by muse, mutect2, varscan2
- CTNND1 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100650251; called by muse, mutect2, varscan2
- DENND1B | c.1262A>T p.D421V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs778289070, COSV99345198; called by muse, mutect2, varscan2
- DGKD | c.2376-2A>G p.X792_splice (on ENST00000264057 / NM_152879.3; = p.X748_splice on NM_003648.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 33/110 reads (30%) | catalogued as rs1247982122, COSV99897413; called by muse, mutect2, varscan2
- DLEC1 | c.2750C>A p.S917* | Nonsense Mutation (SNP) | VAF 79/130 reads (61%) | catalogued as COSV100343276; called by muse, mutect2, varscan2
- DLX5 | c.652_653insG p.P218Rfs*95 | Frame Shift Ins (INS) | VAF 30/92 reads (33%) | catalogued as COSV99756635; called by mutect2, pindel, varscan2
- DPYD | c.2567C>T p.T856I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs752228747, COSV100929327; called by muse, mutect2, varscan2
- DRD3 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs149736958; called by muse, mutect2, varscan2
- EIF2AK3 | c.2807G>A p.R936K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100304060, COSV57552562; called by muse, mutect2, varscan2
- ENPP3 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV100717945; called by muse, mutect2
- EPHA7 | c.28T>C p.W10R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.608); catalogued as rs772524127, COSV100992509; called by muse, mutect2, varscan2
- EPHA8 | c.1315+3A>G | Splice Region (SNP) | VAF 29/93 reads (31%) | catalogued as COSV99385535; called by muse, mutect2, varscan2
- ERICH3 | c.3133G>T p.D1045Y | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100445039, COSV58613418; called by muse, mutect2
- ERICH6 | c.8A>T p.H3L | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV99901933, COSV99902105; called by muse, mutect2, varscan2
- ERVFRD-1 | c.489C>A p.H163Q | Missense Mutation (SNP) | VAF 91/277 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.175); catalogued as COSV100977427; called by muse, mutect2, varscan2
- EXOC6 | c.1311G>T p.R437S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV99592401; called by muse, mutect2
- FCRL3 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100943490; called by muse, mutect2, varscan2
- FCRL4 | c.645G>C p.Q215H | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs1438684483, COSV99620347; called by muse, mutect2, varscan2
- FKTN | c.749G>T p.C250F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99795564; called by muse, mutect2, varscan2
- FLG | c.1970C>A p.S657Y | Missense Mutation (SNP) | VAF 104/363 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64243009; called by muse, mutect2, varscan2
- FLNA | c.1675C>G p.Q559E | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT tolerated (0.33); PolyPhen benign (0.098); catalogued as COSV100774239; called by muse, mutect2, varscan2
- GABRG2 | c.888C>A p.S296= (on ENST00000361925 / NM_001375343.1; = p.S256= on NM_000816.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as COSV62722862; called by muse, mutect2, varscan2
- GAD2 | c.1376G>T p.W459L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV52155045, COSV99393920; called by muse, mutect2, varscan2
- GK2 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100726030; called by muse, mutect2, varscan2
- GLT1D1 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99897414; called by muse, mutect2, varscan2
- GPC2 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99445039; called by muse, mutect2, varscan2
- GPR61 | c.818dup p.T274Dfs*99 | Frame Shift Ins (INS) | VAF 22/85 reads (26%) | catalogued as rs36037823; called by mutect2, pindel, varscan2
- GRIK4 | c.2383C>A p.H795N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs866668506, COSV70803418; called by muse, mutect2, varscan2
- GRIN2A | c.1304C>G p.P435R | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100407687, COSV100410819; called by muse, mutect2, varscan2
- GTF3C6 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100328783; called by muse, mutect2, varscan2
- HOXD4 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100107010, COSV100107094; called by muse, mutect2, varscan2
- HSH2D | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV99507410; called by muse, mutect2, varscan2
- HTR1E | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100541262, COSV100541376; called by muse, mutect2, varscan2
- IFIH1 | c.2380G>T p.E794* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99718830; called by muse, mutect2, varscan2
- IL18RAP | c.101A>T p.Y34F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99962363; called by muse, mutect2, varscan2
- INTU | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as COSV99611975; called by muse, mutect2, varscan2
- IRX1 | c.1386C>A p.N462K | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100116736; called by muse, mutect2, varscan2
- KBTBD3 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV101595720; called by muse, mutect2, varscan2
- KCND3 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100138301; called by muse, mutect2, varscan2
- KCNV1 | c.484A>T p.S162C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV99819388; called by muse, mutect2, varscan2
- KDM2B | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100997636; called by muse, mutect2, varscan2
- KIDINS220 | c.1953G>T p.W651C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99876097, COSV99876315; called by muse, mutect2, varscan2
- KIF21B | c.2375G>C p.R792P | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100145025; called by muse, mutect2, varscan2
- KL | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.082); catalogued as rs891153086, COSV101199188, COSV66308509; called by muse, mutect2, varscan2
- KLHL14 | c.1745T>A p.M582K | Missense Mutation (SNP) | VAF 87/222 reads (39%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.899); catalogued as COSV100839301; called by muse, mutect2, varscan2
- KLHL22 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.947); catalogued as rs758290191, COSV99839432; called by muse, mutect2, varscan2
- KMT2D | c.16295G>T p.R5432L | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM126446, COSV56409187, COSV99985294; called by muse, mutect2, varscan2
- KMT2D | c.2026G>T p.E676* | Nonsense Mutation (SNP) | VAF 34/107 reads (32%) | catalogued as COSV99985297; called by muse, mutect2, varscan2
- LACTB | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs771050457, COSV99979042; called by muse, mutect2, varscan2
- LAMA5 | c.4880G>A p.R1627H | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as rs373128149; called by muse, mutect2, varscan2
- LCMT1 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 100/146 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101111779; called by muse, mutect2, varscan2
- LGI3 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.353); catalogued as rs763691960, COSV100103262; called by muse, mutect2, varscan2
- LOX | c.847A>T p.R283* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99140692; called by muse, mutect2, varscan2
- LRRC4C | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV99539421; called by muse, mutect2, varscan2
- LRRC7 | c.1519G>T p.D507Y (on ENST00000651989 / NM_001370785.2; = p.D474Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50411187, COSV99229278; called by muse, mutect2, varscan2
- MANBA | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV99899109; called by muse, mutect2, varscan2
- MAP2 | c.3714G>C p.E1238D | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV52310360, COSV99561491; called by muse, mutect2, varscan2
- MDN1 | c.4943-1G>A p.X1648_splice | Splice Site (SNP) | VAF 12/41 reads (29%) | catalogued as COSV101021759; called by muse, mutect2, varscan2
- MMP16 | c.1044C>G p.N348K | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV54189033, COSV99690061; called by muse, mutect2, varscan2
- MORC1 | c.1409T>C p.F470S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99227538; called by muse, mutect2, varscan2
- MTPAP | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV99554280; called by muse, mutect2, varscan2
- MUC5B | c.13897A>T p.S4633C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV71596544; called by muse, mutect2, varscan2
- MYO7B | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as rs200024830, COSV101268364; called by mutect2, varscan2
- MZT2A | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | catalogued as COSV100342868; called by muse, mutect2
- NAV3 | c.5935G>A p.D1979N (on ENST00000397909 / NM_001024383.2; = p.D1957N on NM_014903.6) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99894751; called by muse, mutect2, varscan2
- NCAN | c.1085C>A p.T362K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV99388136; called by muse, mutect2, varscan2
- NCOA3 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100508083; called by muse, mutect2, varscan2
- NEB | c.1824G>T p.M608I | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.899); catalogued as COSV99427061; called by muse, mutect2, varscan2
- NEK10 | c.1198C>G p.L400V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100412224; called by muse, mutect2
- NETO2 | c.1348A>C p.S450R | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV100292583; called by muse, mutect2, varscan2
- NFAT5 | c.4225C>G p.Q1409E | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100591149; called by muse, mutect2, varscan2
- NLRP3 | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100276546; called by muse, mutect2, varscan2
- NOTCH3 | c.5404dup p.A1802Gfs*8 | Frame Shift Ins (INS) | VAF 20/84 reads (24%) | catalogued as rs753725730; called by mutect2, varscan2
- NR4A1 | c.1717A>G p.I573V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs761784699, COSV99671640; called by muse, mutect2, varscan2
- NR5A2 | c.655G>A p.A219T (on ENST00000367362 / NM_205860.3; = p.A173T on NM_003822.5) | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV99371563; called by muse, mutect2, varscan2
- NRXN1 | c.4058T>A p.V1353E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100640633; called by muse, mutect2, varscan2
- NTM | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100869371; called by muse, mutect2, varscan2
- NUAK1 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777260; called by muse, mutect2, varscan2
- NUP133 | c.976-2A>G p.X326_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as rs1360538190, COSV99773375; called by muse, mutect2, varscan2
- NWD1 | c.4423G>T p.A1475S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.413); catalogued as rs1332864732, COSV100343547; called by muse, mutect2, varscan2
- OPCML | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV100104361; called by muse, mutect2, varscan2
- OR10J5 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs749463613, COSV100604814, COSV58387610; called by muse, mutect2, varscan2
- OR2T2 | c.781G>C p.V261L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV100737788; called by muse, varscan2
- OR4D10 | c.463C>G p.H155D | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101597023, COSV101597025; called by muse, mutect2, varscan2
- OR51E2 | c.798C>G p.S266R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV101211390; called by muse, mutect2, varscan2
- OR56B4 | c.332A>T p.H111L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100337639, COSV100337689, COSV57204111; called by muse, mutect2, varscan2
- OR6K2 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.472); catalogued as COSV62744267; called by muse, mutect2, varscan2
- OR8K5 | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV100537315, COSV100537322; called by muse, mutect2, varscan2
- OTOA | c.2416G>T p.V806F (on ENST00000286149; = p.V792F on NM_144672.4) | Missense Mutation (SNP) | VAF 53/73 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV99625634; called by muse, mutect2, varscan2
- OVCH1 | c.2079T>A p.F693L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100549107; called by muse, mutect2, varscan2
- PCDHGA12 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 35/52 reads (67%) | catalogued as COSV99341966; called by muse, mutect2, varscan2
- PCDHGA3 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 93/170 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs780017426, COSV53987248, COSV99545440; called by muse, mutect2, varscan2
- PCLO | c.3953A>G p.K1318R | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as COSV100436803; called by muse, mutect2, varscan2
- PI4K2A | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV101033353; called by muse, mutect2, varscan2
- PI4KB | c.1432A>T p.S478C (on ENST00000368873 / NM_001369623.1; = p.S490C on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV99650084; called by muse, mutect2, varscan2
- PKHD1 | c.7592T>A p.L2531Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100584339; called by muse, mutect2, varscan2
- PLEC | c.1959G>C p.E653D (on ENST00000322810 / NM_201380.4; = p.E543D on NM_000445.5) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100518206; called by muse, mutect2, varscan2
- PPP6R3 | c.1350G>C p.E450D (on ENST00000393800 / NM_001352375.2; = p.E399D on NM_018312.5) | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.225); catalogued as COSV99677335; called by muse, mutect2, varscan2
- PRAMEF12 | c.50T>G p.L17R | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748229744, COSV100743567; called by muse, mutect2, varscan2
- PSG3 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1384469320, COSV100549214; called by muse, mutect2, varscan2
- RAB8A | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV56293399; called by muse, mutect2, varscan2
- RAMP3 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as rs376505514, COSV99642413; called by muse, mutect2, varscan2
- REG1B | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV100521501, COSV59304726; called by muse, mutect2, varscan2
- ROBO4 | c.2395G>T p.A799S | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs764801858, COSV60628738; called by muse, mutect2, varscan2
- RP1 | c.3452A>G p.H1151R | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV55114802, COSV99608598; called by muse, mutect2, varscan2
- RSAD2 | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101150012, COSV65907993; called by muse, mutect2, varscan2
- RTL4 | c.695T>G p.L232R | Missense Mutation (SNP) | VAF 100/167 reads (60%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.576); catalogued as COSV100466110; called by muse, mutect2, varscan2
- RUNDC3B | c.833T>A p.L278H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100407260; called by muse, mutect2, varscan2
- RYR1 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM061939, CM140861, COSV62087706, COSV62099686; called by muse, mutect2, varscan2
- RYR1 | c.6491C>G p.S2164W | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473972613, COSV100615085, COSV100616770; called by muse, mutect2, varscan2
- SACM1L | c.1006A>G p.I336V | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101203790; called by muse, mutect2, varscan2
- SBNO2 | c.2207A>G p.E736G | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV100684967; called by muse, mutect2, varscan2
- SCN11A | c.2362G>T p.V788F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100182297; called by muse, mutect2, varscan2
- SEC16B | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV57628706, COSV57631420; called by muse, mutect2, varscan2
- SEPTIN14 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101193420; called by muse, mutect2, varscan2
- SIGLEC8 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.021); catalogued as COSV100367363; called by muse, mutect2, varscan2
- SIPA1L3 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99730199; called by muse, mutect2, varscan2
- SLC12A1 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 36/71 reads (51%) | catalogued as rs773855120, COSV100372536; called by muse, mutect2, varscan2
- SLC22A10 | c.1525G>A p.G509S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.609); catalogued as COSV100235664; called by muse, mutect2, varscan2
- SLC24A4 | c.1697T>C p.L566P | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100105973; called by muse, mutect2, varscan2
- SLC27A2 | c.519A>T p.K173N | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.281); catalogued as COSV99983058; called by muse, mutect2, varscan2
- SLC6A16 | c.1594A>G p.R532G | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100242925; called by muse, mutect2, varscan2
- SLC6A19 | c.1863C>A p.S621R | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs1384126621, COSV99722623; called by muse, mutect2, varscan2
- SLCO6A1 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV101134886; called by muse, mutect2, varscan2
- SPDL1 | c.1621G>C p.D541H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1439233067, COSV99517716; called by muse, mutect2, varscan2
- SSTR3 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); catalogued as COSV60730714; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | PolyPhen benign (0.001); catalogued as rs771158980, COSV100084994; called by muse, mutect2, varscan2
- STYXL2 | c.1991C>A p.S664Y | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99609199, COSV99609785; called by muse, mutect2, varscan2
- SV2A | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.37); catalogued as COSV100974970, COSV100975247; called by muse, mutect2, varscan2
- SYNE1 | c.7821C>G p.N2607K (on ENST00000367255 / NM_182961.4; = p.N2614K on NM_033071.3) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.08); catalogued as COSV99575989; called by muse, mutect2, varscan2
- SYNJ1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs111886678, COSV59151176; called by muse, mutect2, varscan2
- SZT2 | c.2568G>T p.Q856H | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as COSV100987612; called by muse, mutect2, varscan2
- TDRD5 | c.2348G>T p.W783L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as COSV99676984; called by muse, mutect2, varscan2
- TENT5D | c.542A>T p.D181V | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100382925; called by muse, varscan2
- TEX44 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs374219461; called by muse, mutect2
- THNSL2 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs1369365555, COSV59085460; called by muse, mutect2, varscan2
- TMEM190 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99404373; called by muse, mutect2, varscan2
- TMEM37 | c.291G>T p.L97F | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99191704; called by muse, mutect2, varscan2
- TPTE | c.688T>C p.Y230H (on ENST00000618007 / NM_199261.4; = p.Y212H on NM_199259.4) | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs745876374; called by muse, mutect2, varscan2
- TRAPPC6B | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV100351315; called by muse, mutect2
- TRHDE | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99672155; called by muse, mutect2, varscan2
- TRMT10C | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99998368; called by muse, mutect2, varscan2
- TSPEAR | c.34C>G p.P12A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100555255; called by muse, mutect2, varscan2
- TUBB4A | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99900134; called by muse, mutect2, varscan2
- UBE2J2 | c.128A>T p.E43V | Missense Mutation (SNP) | VAF 95/225 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100231349; called by muse, mutect2, varscan2
- UHRF1BP1L | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99692055; called by muse, mutect2, varscan2
- UROC1 | c.1491G>C p.E497D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.808); catalogued as COSV99332249; called by muse, mutect2, varscan2
- VAT1L | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.761); catalogued as rs1428257981, COSV100214069; called by muse, mutect2, varscan2
- VCPIP1 | c.3137G>T p.R1046M | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100125760; called by muse, mutect2, varscan2
- WAPL | c.2336T>C p.V779A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99556596; called by muse, mutect2, varscan2
- XIRP2 | c.1192G>T p.E398* (on ENST00000628543; = p.E573* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV54745115; called by muse, mutect2, varscan2
- XIRP2 | c.6407C>A p.P2136H (on ENST00000628543; = p.P2311H on NM_152381.6) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99746624; called by muse, mutect2, varscan2
- XIRP2 | c.7144G>T p.E2382* (on ENST00000628543; = p.E2557* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as COSV99746626; called by muse, mutect2, varscan2
- ZBTB7B | c.346G>T p.A116S (on ENST00000292176; = p.A150S on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV99421486; called by muse, mutect2, varscan2
- ZDBF2 | c.1107C>G p.I369M | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1357570648, COSV100985420, COSV65629657; called by muse, mutect2, varscan2
- ZEB2 | c.1483T>C p.C495R | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.105); catalogued as COSV100356720; called by muse, mutect2, varscan2
- ZIM2 | c.1198T>A p.C400S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99690165; called by muse, mutect2, varscan2
- ZNF347 | c.1721G>C p.C574S | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1210679791, COSV100498322, COSV100498404; called by muse, mutect2, varscan2
- ZNF407 | c.10A>C p.S4R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99996560; called by muse, mutect2, varscan2
- ZNF439 | c.1458G>T p.R486S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV100397546; called by muse, mutect2, varscan2
- ZNF76 | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV99987897; called by muse, mutect2, varscan2
- ZNF92 | c.552G>T p.M184I (on ENST00000328747 / NM_152626.4; = p.M115I on NM_007139.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV100165938; called by muse, mutect2, varscan2
- CLN3 | c.941del p.R314Pfs*39 (on ENST00000360019 / NM_001286104.2; = p.R338Pfs*39 on NM_000086.2) | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- FAM83B | c.2999dup p.M1000Ifs*12 | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- KMT2E | c.517del p.A173Qfs*43 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- MLF2 | c.363_366del p.Y121* | Frame Shift Del (DEL) | VAF 59/194 reads (30%) | called by mutect2, pindel, varscan2
- MRC1 | c.2111+1G>A p.X704_splice | Splice Site (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- NDUFA5 | c.33dup p.V12Cfs*22 | Frame Shift Ins (INS) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- NOS1 | c.2061del p.M688Cfs*52 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, varscan2
- OASL | c.850del p.H284Tfs*47 | Frame Shift Del (DEL) | VAF 29/103 reads (28%) | called by mutect2, pindel, varscan2
- RP1L1 | c.257del p.G86Afs*71 | Frame Shift Del (DEL) | VAF 33/58 reads (57%) | called by mutect2, pindel, varscan2
- SDE2 | c.875_896del p.H292Lfs*32 | Frame Shift Del (DEL) | VAF 42/162 reads (26%) | called by mutect2, pindel, varscan2
- SLITRK5 | c.20del p.P7Qfs*2 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.1800G>T p.Q600H | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TJP2 | c.790del p.A264Pfs*47 | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- XKR3 | c.1190A>T p.Y397F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ABCC6 | c.2964C>T p.G988= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs548522940, COSV99229481; called by muse, mutect2, varscan2
- ADAMTS20 | c.3522C>A p.A1174= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV67133358; called by muse, mutect2, varscan2
- AQP2 | c.693G>A p.S231= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs761719425, COSV99550919; called by muse, mutect2, varscan2
- ATP1B2 | c.360T>G p.S120= | Silent (SNP) | VAF 96/163 reads (59%) | catalogued as COSV100006956; called by muse, mutect2, varscan2
- CACNA1G | c.3120C>A p.I1040= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100662404; called by muse, mutect2, varscan2
- CACNA1S | c.4818C>A p.G1606= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV100755315; called by muse, mutect2, varscan2
- CAPN9 | c.18G>T p.R6= | Silent (SNP) | VAF 83/186 reads (45%) | catalogued as COSV99680998; called by muse, mutect2, varscan2
- CCDC62 | c.1782C>G p.S594= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV99457603; called by muse, mutect2, varscan2
- CISD2 | c.330C>T p.C110= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs587780892, COSV99913720; called by muse, varscan2
- CNTNAP2 | c.2686C>T p.L896= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV100670785; called by muse, mutect2, varscan2
- CPNE7 | c.1191G>A p.R397= | Silent (SNP) | VAF 54/70 reads (77%) | catalogued as COSV99255079; called by muse, mutect2, varscan2
- CXCR1 | c.861G>C p.L287= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as rs1361759450, COSV99826402; called by muse, mutect2, varscan2
- DISP1 | c.3555T>C p.S1185= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV99452037; called by muse, mutect2, varscan2
- ENOX1 | c.135C>A p.P45= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs772792203, COSV99816937; called by muse, mutect2, varscan2
- EPHA5 | c.2217A>G p.L739= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as COSV99900824; called by muse, mutect2, varscan2
- FAAP20 | c.477C>T p.T159= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV101052054; called by muse, mutect2, varscan2
- FAM120B | c.741A>G p.L247= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV53006937; called by muse, mutect2, varscan2
- FOXN3 | c.861G>T p.L287= (on ENST00000261302; = p.L265= on NM_005197.4) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99727228; called by muse, mutect2, varscan2
- GAB2 | c.1506C>T p.P502= (on ENST00000361507 / NM_080491.3; = p.P464= on NM_012296.3) | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as COSV100416781; called by muse, mutect2, varscan2
- GBP2 | c.1035G>A p.T345= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs537194337, COSV100975424; called by muse, mutect2, varscan2
- GTF3C1 | c.3324G>A p.L1108= | Silent (SNP) | VAF 91/139 reads (65%) | catalogued as rs1567394079, COSV100649656; called by muse, mutect2, varscan2
- HACD1 | c.420G>C p.V140= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100778512; called by muse, mutect2, varscan2
- HECW2 | c.2748G>T p.L916= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV99648615; called by muse, mutect2, varscan2
- HOXB1 | c.799C>A p.R267= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as COSV53317805, COSV53317930; called by muse, mutect2, varscan2
- KAT5 | c.1053C>T p.I351= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as rs915081547, COSV100384035; called by muse, mutect2
- KSR1 | c.144C>T p.I48= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100123467; called by mutect2, varscan2
- LRP1B | c.5370G>C p.L1790= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs780323925, COSV101260009; called by mutect2, varscan2
- LRP5 | c.525G>C p.R175= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99592549; called by muse, mutect2, varscan2
- LTV1 | c.723G>C p.T241= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100849618; called by muse, mutect2, varscan2
- MAGI2 | c.2502C>T p.A834= | Silent (SNP) | VAF 62/163 reads (38%) | catalogued as rs144611762; called by muse, mutect2, varscan2
- MUC20 | c.1446C>T p.S482= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV57849955, COSV57851120; called by muse, mutect2, varscan2
- MUC6 | c.5568C>T p.I1856= | Silent (SNP) | VAF 108/569 reads (19%) | catalogued as rs1222685266, COSV101424759; called by muse, varscan2
- NOL4 | c.1473T>C p.S491= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99308078; called by muse, mutect2, varscan2
- NOTUM | c.1209G>A p.K403= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101293823; called by muse, mutect2, varscan2
- NSUN6 | c.672C>T p.A224= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs61840806, COSV101045938, COSV66036093; called by muse, mutect2, varscan2
- OAS3 | c.93C>A p.R31= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99966521; called by muse, mutect2
- OBSCN | c.22803A>T p.T7601= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as COSV100803807, COSV100805258; called by muse, mutect2, varscan2
- OR4D10 | c.462C>A p.V154= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV101597024; called by muse, mutect2, varscan2
- OR52E8 | c.681G>T p.L227= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs138364828, COSV101190857; called by mutect2, varscan2
- PAPPA2 | c.1986C>G p.P662= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100866708, COSV100867070, COSV62774779; called by muse, mutect2, varscan2
- PCDHB13 | c.1179C>A p.L393= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as COSV53395939; called by muse, mutect2, varscan2
- PCDHGA12 | c.1302G>C p.T434= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as COSV52744306, COSV99340966, COSV99341962; called by muse, mutect2, varscan2
- PCDHGB4 | c.1572C>G p.R524= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV53905136, COSV99545441; called by muse, mutect2, varscan2
- PIGG | c.1521G>C p.A507= (on ENST00000453061 / NM_001127178.3; = p.A499= on NM_017733.4) | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV99574168, COSV99574272; called by muse, mutect2, varscan2
- PLXNA3 | c.2307A>T p.G769= | Silent (SNP) | VAF 41/54 reads (76%) | catalogued as COSV100860209; called by muse, mutect2, varscan2
- PLXNC1 | c.1116C>A p.I372= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs770449252, COSV99313688; called by muse, mutect2, varscan2
- PPL | c.4906C>T p.L1636= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as COSV99278516; called by muse, varscan2
- SERAC1 | c.369A>G p.T123= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as rs1398924303, COSV100894888; called by muse, mutect2, varscan2
- SERTAD4 | c.999A>G p.K333= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100882655; called by muse, mutect2, varscan2
- SH3BP4 | c.2214G>C p.S738= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100749286, COSV60644279; called by muse, mutect2, varscan2
- SIRPA | c.639C>A p.A213= | Silent (SNP) | VAF 100/125 reads (80%) | catalogued as COSV100605346; called by muse, mutect2, varscan2
- SLC2A4 | c.357G>A p.A119= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as rs375581164; called by muse, mutect2, varscan2
- SLC5A4 | c.1932C>A p.A644= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99832110; called by muse, mutect2, varscan2
- SLC6A18 | c.1353C>A p.V451= | Silent (SNP) | VAF 90/185 reads (49%) | catalogued as COSV99722624; called by muse, mutect2, varscan2
- SLC8A2 | c.693G>A p.L231= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99370274; called by muse, mutect2, varscan2
- SPEG | c.2709G>T p.L903= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as COSV100405462, COSV56667942; called by muse, mutect2, varscan2
- TBC1D7 | c.591G>A p.A197= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs375163232, COSV58245519; called by muse, mutect2, varscan2
- TEX44 | c.177C>A p.P59= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as COSV100009851, COSV58355181; called by muse, mutect2
- TFAP2B | c.930C>T p.S310= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as rs761063428, COSV99540743; called by muse, mutect2, varscan2
- TIMD4 | c.327G>C p.V109= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99192862; called by muse, mutect2, varscan2
- TMEM132D | c.3228C>A p.V1076= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as COSV101243050; called by muse, mutect2, varscan2
- TRIM63 | c.759G>A p.L253= | Silent (SNP) | VAF 57/131 reads (44%) | catalogued as COSV100958186; called by muse, mutect2, varscan2
- ZBED9 | c.1290A>G p.A430= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV101509369; called by muse, varscan2
- ZP4 | c.786T>C p.T262= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs566640263, COSV100850750; called by muse, mutect2, varscan2
- ACP4 | chr19:50798139 C>A | 3'Flank (SNP) | VAF 62/192 reads (32%) | catalogued as COSV54517110; called by muse, mutect2, varscan2
- DCHS2 | n.7460C>G | RNA (SNP) | VAF 32/51 reads (63%) | catalogued as COSV100602497; called by muse, mutect2, varscan2
- DPP6 | c.*396C>A | 3'UTR (SNP) | VAF 43/140 reads (31%) | catalogued as COSV100127725; called by muse, mutect2, varscan2
- DST | c.21999+494C>G | Intron (SNP) | VAF 25/63 reads (40%) | catalogued as COSV99759302; called by muse, mutect2, varscan2
- FAM83D | chr20:38926362 G>T | 5'Flank (SNP) | VAF 8/68 reads (12%) | catalogued as COSV54156730, COSV99465456; called by muse, varscan2
- MAPK14 | c.763-2347G>T | Intron (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100005142; called by muse, mutect2, varscan2
- RASSF1 | c.369+592G>C | Intron (SNP) | VAF 26/46 reads (57%) | catalogued as COSV99205805; called by muse, mutect2, varscan2
- SNRPN | c.-329G>T | 5'UTR (SNP) | VAF 19/30 reads (63%) | catalogued as rs749134956, COSV100578554; called by muse, mutect2, varscan2
- SON | c.6657+119G>T | Intron (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99279551; called by muse, varscan2
